Gene-level copy-number profile of tumor specimen ALCH-B2RC-TTP1-A from ALCHEMIST case ALCH-B2RC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.5 years (23,202 days).
Specimen ALCH-B2RC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 744aa3ca-72f3-4618-a986-453a11119e9e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2RC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/f84f42fe-db34-40fb-b953-bf86bc914a5b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 591; copy number 1: 6,691; copy number 2: 50,604; copy number 3: 959; copy number 4: 57; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,974,502–17,011,928, 5 genes: MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3.
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr4:1,617,915–1,684,261, 2 genes (within-gene range 0–1): FAM53A, Y_RNA.
- chr11:134,378,504–134,412,242, 1 gene: B3GAT1.
- chr12:131,801,315–131,851,783, 3 genes: RNA5SP378, RNU6-1017P, MMP17.
- chr15:25,172,635–25,268,551, 47 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1, SNORD115-45, SNORD115-46, SNORD115-47.
- chr21:45,974,489–45,974,953, 1 gene: AJ011932.1.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,341,859, 1 gene, copy number 7: CR383658.1.

Autosomal genes at a single copy (total copy number 1): 4,381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
